Somatic mutation profile of tumor specimen TCGA-FU-A3YQ-01A (aliquot TCGA-FU-A3YQ-01A-11D-A22X-09) from TCGA case TCGA-FU-A3YQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G1; Age at diagnosis: 35.1 years (12,816 days).
Specimen TCGA-FU-A3YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07179577-eb5f-42e7-8297-ba80e72f5923.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A3YQ-10A (Blood Derived Normal), aliquot TCGA-FU-A3YQ-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6830ff6e-a2a4-493e-ab80-f6d94717e90c

The open-access MAF lists 82 somatic variants for this specimen: 59 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 20, Nonsense Mutation 5, 5'Flank 3, Splice Site 2, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.4008_4013del p.X1336_splice | Splice Site (DEL) | VAF 11/73 reads (15%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AASDH | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV52706473; called by muse, mutect2
- ABI3 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as rs779746761, COSV56799987; called by muse, mutect2, varscan2
- AC013489.1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51551226; called by muse, mutect2, varscan2
- ADAMTS12 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.249); catalogued as COSV61260100, COSV61262472; called by muse, mutect2
- ANKRD13B | c.753G>C p.E251D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67473794; called by muse, mutect2, varscan2
- ANKS1B | c.2594G>C p.R865T (on ENST00000547776 / NM_152788.4; = p.R91T on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV60362771; called by muse, mutect2, varscan2
- ATP10A | c.2984C>A p.A995D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63517075; called by muse, mutect2, varscan2
- BRD2 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.316); catalogued as COSV66373228; called by muse, mutect2, varscan2
- CACNA1D | c.977G>T p.C326F | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99859812; called by muse, mutect2
- CACNA1H | c.5917G>A p.A1973T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1003957584, COSV52354414; called by muse, mutect2, varscan2
- CEP250 | c.2857C>T p.Q953* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as rs1298884778, COSV61169948; called by muse, mutect2, varscan2
- CEP350 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV62485864; called by muse, mutect2
- CFAP43 | c.3781G>A p.E1261K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV100829487, COSV63853049; called by muse, mutect2, varscan2
- DEPDC5 | c.2882C>A p.S961* (on ENST00000400246; = p.S1030* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as COSV56697057, COSV56699618; called by muse, mutect2, varscan2
- DNAAF1 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs769351361, COSV57577160; called by muse, mutect2, varscan2
- ELP2 | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | catalogued as COSV60850867; called by muse, mutect2, varscan2
- EMC2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/67 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.191); catalogued as COSV99624527; called by muse, mutect2, varscan2
- FLNC | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs777415462, COSV57955581; called by muse, mutect2
- H1-1 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs776390963, COSV55119404; called by muse, mutect2, varscan2
- INTS13 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV53902536; called by muse, mutect2, varscan2
- KIAA0513 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50741304, COSV50743601; called by muse, mutect2, varscan2
- KIF13B | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101568718, COSV72879484; called by muse, mutect2, varscan2
- LACTB | c.1119-1G>C p.X373_splice | Splice Site (SNP) | VAF 5/26 reads (19%) | catalogued as COSV56055939, COSV99979110; called by muse, mutect2, varscan2
- MARF1 | c.3868C>T p.H1290Y | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60023214; called by muse, varscan2
- MARF1 | c.3760C>G p.Q1254E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as COSV60023231; called by muse, mutect2, varscan2
- MARF1 | c.3391C>G p.H1131D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60023249; called by muse, mutect2, varscan2
- MYO9B | c.4611C>G p.I1537M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as COSV68278960; called by muse, mutect2, varscan2
- MZF1 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV53041491; called by muse, mutect2, varscan2
- PRKDC | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV58051469; called by muse, mutect2
- PRRX2 | c.459G>C p.Q153H | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65242154; called by muse, mutect2, varscan2
- PTPRF | c.5311G>C p.E1771Q | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63444834; called by muse, mutect2, varscan2
- RAPGEF4 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV51388259; called by muse, mutect2, varscan2
- RASGEF1C | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100746319; called by muse, mutect2
- RBMS1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV62352870; called by muse, mutect2, varscan2
- RPL3 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV53365323; called by muse, mutect2, varscan2
- RUNX3 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs764020894, COSV58243694; called by muse, mutect2, varscan2
- SEC24B | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as rs758546508, COSV54499019; called by muse, mutect2, varscan2
- SI | c.4990G>C p.D1664H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV52276006, COSV52277545; called by muse, mutect2, varscan2
- SPA17 | c.418_421del p.N140Vfs*24 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs1251208076; called by mutect2, pindel, varscan2
- SPAG16 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59091646; called by muse, mutect2, varscan2
- SPTBN5 | c.9337G>A p.E3113K | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs764933431, COSV58020341; called by muse, mutect2, varscan2
- SQLE | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV56280680; called by muse, mutect2, varscan2
- TAS2R42 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV62084593; called by mutect2, varscan2
- TP53INP1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as COSV61331396; called by muse, mutect2, varscan2
- TSACC | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.31); catalogued as COSV100966221, COSV100966228; called by muse, mutect2
- TUBA1B | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV60137003, COSV60138363; called by muse, mutect2, varscan2
- ULK2 | c.2554G>C p.E852Q | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV64445647; called by muse, mutect2, varscan2
- URAD | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60381273; called by muse, mutect2, varscan2
- VAC14 | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as COSV55753373; called by muse, mutect2, varscan2
- VCAN | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54104644; called by muse, mutect2
- VPS29 | c.309G>C p.Q103H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as COSV62194854; called by muse, mutect2, varscan2
- VPS33B | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV60980086; called by muse, mutect2, varscan2
- WWC1 | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV54650532; called by muse, mutect2, varscan2
- XPO6 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1426475966, COSV58966242; called by muse, mutect2, varscan2
- ZFYVE28 | c.904G>T p.G302* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV52110904; called by muse, mutect2
- ZNF536 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV62819411; called by muse, mutect2
- ZNF84 | c.2160C>G p.F720L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV59654171; called by muse, mutect2, varscan2
- RAI1 | c.2602G>T p.E868* | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ABCA2 | c.2277G>A p.A759= (on ENST00000614293; = p.A729= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs746344152, COSV99688365; called by muse, varscan2
- ABL2 | c.573C>T p.I191= (on ENST00000502732 / NM_007314.4; = p.I176= on NM_005158.5) | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV61013852; called by muse, mutect2, varscan2
- DALRD3 | c.951G>A p.V317= (on ENST00000341949 / NM_001009996.3; = p.V150= on NM_018114.5) | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV58244931; called by muse, mutect2, varscan2
- EFCAB7 | c.483C>T p.I161= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV64314469; called by muse, mutect2, varscan2
- FREM1 | c.4365C>T p.F1455= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs370099735; called by muse, mutect2, varscan2
- GGT7 | c.1815G>T p.L605= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs1568928616, COSV60540799; called by muse, mutect2, varscan2
- IGHA1 | c.210G>T p.L70= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs762385618; called by muse, mutect2, varscan2
- IQCG | c.1311G>A p.K437= | Silent (SNP) | VAF 18/212 reads (8%) | catalogued as COSV99502659; called by muse, mutect2
- MBD3 | c.606G>A p.K202= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs778658441, COSV50083283; called by muse, mutect2, varscan2
- MMP11 | c.249C>T p.P83= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs144178537, COSV53157500; called by muse, mutect2, varscan2
- MROH1 | c.2202G>A p.E734= | Silent (SNP) | VAF 19/176 reads (11%) | called by muse, mutect2, varscan2
- NFIC | c.1290C>G p.L430= (on ENST00000443272 / NM_001245002.2; = p.L421= on NM_205843.3) | Silent (SNP) | VAF 36/188 reads (19%) | catalogued as COSV59412433; called by muse, varscan2
- NPAS1 | c.1371G>A p.Q457= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV53409251; called by muse, mutect2, varscan2
- OR8H2 | c.135G>A p.G45= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV57944483; called by muse, mutect2, varscan2
- PNPLA8 | c.1335C>A p.L445= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV57552351; called by muse, mutect2
- SCG5 | c.282C>T p.I94= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs529878476, COSV55706222; called by muse, mutect2, varscan2
- SLITRK5 | c.1980G>A p.S660= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV61522773; called by muse, mutect2, varscan2
- TBC1D10A | c.1161G>A p.L387= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs776661955, COSV53164179; called by muse, mutect2, varscan2
- TYR | c.90G>C p.L30= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV54473920, COSV54474944; called by muse, mutect2, varscan2
- ZBTB22 | c.777G>A p.L259= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV56469135; called by muse, mutect2
- AP000769.3 | chr11:65503901 G>A | 5'Flank (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504523 G>C | 5'Flank (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505056 G>A | 5'Flank (SNP) | VAF 4/31 reads (13%) | catalogued as rs746237513; called by muse, mutect2, varscan2
